CCDI case PBBJLB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7321b64f-bb9a-460d-923d-54b292e47240

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,646 days).

Biospecimens (3 samples)
- Sample 0DA2WW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DA2XG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DA2XH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
